Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5754, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5754-01A (Primary Tumor).

Diagnosis

1. Prostate: poorly differentiated bilateral adenocarcinoma of the prostate across the organ, mainly in the peripheral zone (Gleason 4+5=9 with minimal Gleason 3 portion; Gleason 4: approx. 90%, Gleason 5: 5%, Gleason 3: <5%). Maximum tumor diameter 33 mm. Tumor involves approx. 80% of total gland. Tumor infiltration of right basal periprostatic fatty tissue (infiltration front 1 mm wide, 0.5mm deep). Extensive bilateral seminal vesicle involvement. Extensive perineural tumor infiltration. Tumor contact with the color-labeled surgical resection margin in the left anterior region on a block level (contact line 1.5 mm; Gleason pattern 4 here). Lymph vessel invasion by the tumor in places. Additional foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.
2. Right external lymph nodes: a lymph node with a 1.2 cm carcinoma metastasis. Three tumor-free lymph nodes (1/4).
3. Right obturator fossa: a tumor-free lymph node (0/1).
4. Right internal lymph nodes: tumor-free fatty tissue resection material with a tumor-free microscopic lymph node (0/1).
5. Left external lymph nodes: two tumor-free lymph nodes (0/2).
6. Lymph nodes of left obturator fossa: two lymph node carcinoma metastases measuring up to 3.5 cm and extending over the capsule (2/2).
7. Left internal lymph nodes: tumor-free fatty tissue with tumor-free parts of a microscopic lymph node (0/1).

Tumor classification

pT3b, maximum tumor diameter 33 mm. Tumor involving approx. 80% of the total prostate, Gleason 4+5=9 with minimal Gleason 3 portions (Gleason 4: approx. 90%, Gleason 5: 5%, Gleason 3: <5%), L1, R1, pN1 (3/11)

Remark

In the prior punch biopsies carcinoma tissue was obtained at all sampling sites with an overall Gleason pattern of 4+3=7 with tertiary grade 5. This prostatectomy preparation thus shows an overall pattern of 4+5=9 with small Gleason 3 portions on the basis of the larger Gleason 5 portion, as described above.

Follow-up report

Immunohistochemistry: 2x CD240 and CD31 (BR4, BL2).

The reported immunohistochemical investigation of the adenocarcinoma of the prostate showed lymph vessel invasion. There was no evidence of blood vessel invasion.

Final tumor classification:

pT3b, maximum tumor diameter 3.3 cm, tumor involves 80% of the prostate in total, Gleason 4+5=9 minimal Gleason 3 tumor (Gleason 4: 90%, Gleason 5: 5%, Gleason 3: < 5%), L1, V0, pN1 (3/11), R1.

Source: NCI Genomic Data Commons file b202ecbd-6744-456a-afb5-88014eb6922c (TCGA-CH-5754.6C02CB0E-6826-46F0-8A9F-90F43CC1405C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).